Somatic mutation profile of tumor specimen TCGA-FG-A70Z-01A (aliquot TCGA-FG-A70Z-01A-12D-A33T-08) from TCGA case TCGA-FG-A70Z, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 54.0 years (19,717 days).
Specimen TCGA-FG-A70Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd43869e-eec9-4db8-84c9-6047b21be7e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-A70Z-10A (Blood Derived Normal), aliquot TCGA-FG-A70Z-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3009de1-926a-40ba-92bf-2780cf1b7b00

The open-access MAF lists 64 somatic variants for this specimen: 42 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 21, Nonsense Mutation 5, Splice Site 3, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 732/832 reads (88%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATP10B | c.2548C>T p.R850W | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs754741809, COSV59142627; called by muse, mutect2, varscan2
- COL4A5 | c.65A>T p.Q22L | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as CD107366, COSV100087308; called by muse, mutect2, varscan2
- EGFR | c.3427C>T p.Q1143* | Nonsense Mutation (SNP) | VAF 762/884 reads (86%) | catalogued as COSV99289491; called by muse, mutect2, varscan2
- ENPEP | c.929A>G p.Y310C | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99487389; called by muse, mutect2, varscan2
- F8 | c.4427G>A p.R1476K | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100811413; called by muse, mutect2
- FGD5 | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs760161782, COSV53245111; called by muse, mutect2, varscan2
- FLNA | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs1557180284, COSV100774505; called by muse, mutect2
- GPR20 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs370181787; called by muse, mutect2, varscan2
- GRHL3 | c.650A>G p.E217G (on ENST00000350501 / NM_198174.3; = p.E222G on NM_021180.3) | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.272); catalogued as COSV99359234; called by muse, mutect2, varscan2
- GRK3 | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as COSV100151351; called by muse, mutect2, varscan2
- GRM4 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs572550212, COSV65210035, COSV65215900; called by muse, mutect2, varscan2
- HECTD2 | c.145G>C p.D49H | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV99978398; called by muse, mutect2, varscan2
- HMCN1 | c.14312G>A p.R4771Q | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.687); catalogued as rs141397809, COSV99633123; called by muse, mutect2, varscan2
- KRT25 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 137/399 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.329); catalogued as rs754517768, COSV100380021, COSV56444403; called by muse, mutect2, varscan2
- LAMA5 | c.2745G>T p.R915S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as COSV99439117; called by muse, mutect2, varscan2
- MARS1 | c.1171C>T p.H391Y | Missense Mutation (SNP) | VAF 72/1127 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV100007242; called by muse, mutect2
- MBNL3 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 117/340 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.085); catalogued as COSV100898456; called by muse, mutect2, varscan2
- NCKAP5 | c.3055C>T p.R1019* | Nonsense Mutation (SNP) | VAF 20/58 reads (34%) | catalogued as rs1262125485, COSV100491184; called by muse, mutect2, varscan2
- OR8G1 | c.206T>G p.I69S | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.265); catalogued as COSV100422351; called by muse, mutect2, varscan2
- PLCXD3 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.968); catalogued as rs751201584, COSV60614634; called by muse, mutect2, varscan2
- PRG4 | c.3653G>A p.R1218H | Missense Mutation (SNP) | VAF 73/254 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201785504, COSV63355674, COSV63356193; called by muse, mutect2, varscan2
- PTCHD4 | c.2527G>A p.V843I | Missense Mutation (SNP) | VAF 78/280 reads (28%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.959); catalogued as rs755323079, COSV100260538; called by muse, mutect2, varscan2
- QSOX2 | c.1103C>T p.P368L | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs781617567, COSV62393229; called by muse, mutect2, varscan2
- RAPSN | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.786); catalogued as rs374588028, CM094599, COSV54083922; called by muse, mutect2, varscan2
- RIPK4 | c.1801G>A p.V601M (on ENST00000352483; = p.V553M on NM_020639.3) | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs757583864, COSV100204814; called by muse, mutect2, varscan2
- RNF112 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.787); catalogued as rs577137511, COSV101465403; called by muse, mutect2, varscan2
- RPS3 | c.299C>G p.A100G | Missense Mutation (SNP) | VAF 69/217 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV99584325; called by muse, mutect2, varscan2
- SEC16B | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs201675705; called by muse, mutect2, varscan2
- SLC28A3 | c.1150-2A>T p.X384_splice | Splice Site (SNP) | VAF 68/189 reads (36%) | catalogued as COSV100883210; called by muse, mutect2, varscan2
- SLC6A16 | c.1929G>A p.W643* | Nonsense Mutation (SNP) | VAF 16/51 reads (31%) | catalogued as COSV100242663; called by muse, mutect2, varscan2
- SLC6A8 | c.1767+2T>A p.X589_splice | Splice Site (SNP) | VAF 7/16 reads (44%) | catalogued as COSV99465868; called by muse, mutect2, varscan2
- SLC7A5 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1299223288, COSV55366779; called by muse, mutect2, varscan2
- SORCS1 | c.3232C>T p.R1078* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as COSV53849388, COSV99551147; called by muse, mutect2, varscan2
- TJP1 | c.744G>C p.L248F | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100632574; called by muse, mutect2, varscan2
- TMEM252 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs533109920, COSV66065625, COSV66066063; called by muse, mutect2, varscan2
- TMTC1 | c.938+2T>G p.X313_splice (on ENST00000539277 / NM_001193451.2; = p.X205_splice on NM_175861.3) | Splice Site (SNP) | VAF 26/102 reads (25%) | catalogued as COSV99759293; called by muse, mutect2, varscan2
- TTN | c.2422C>T p.R808C (on ENST00000591111; = p.R762C on NM_003319.4) | Missense Mutation (SNP) | VAF 54/176 reads (31%) | PolyPhen possibly damaging (0.862); catalogued as rs149155733; ClinVar: uncertain significance; called by muse, mutect2
- USP15 | c.1445G>C p.R482T (on ENST00000280377 / NM_001351159.2; = p.R453T on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/243 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.099); catalogued as COSV99739090; called by muse, mutect2
- WDHD1 | c.2582T>C p.V861A | Missense Mutation (SNP) | VAF 128/418 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0.036); catalogued as COSV100777565; called by muse, mutect2, varscan2
- ZP4 | c.389T>C p.M130T | Missense Mutation (SNP) | VAF 137/409 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV100850648; called by muse, mutect2, varscan2
- GGNBP2 | c.1240A>T p.S414C | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- ADAMTS20 | c.1083C>T p.D361= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV101239124; called by muse, mutect2, varscan2
- ALX4 | c.963C>T p.C321= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as rs561018820, COSV100240993, COSV61328542; called by muse, mutect2, varscan2
- APOA4 | c.1005C>T p.D335= | Silent (SNP) | VAF 55/153 reads (36%) | catalogued as rs545034382, COSV100759248; called by muse, mutect2, varscan2
- BIN2 | c.24C>T p.G8= | Silent (SNP) | VAF 31/116 reads (27%) | catalogued as rs1162419242, COSV53330175; called by muse, mutect2, varscan2
- FAM220A | c.351G>A p.V117= | Silent (SNP) | VAF 27/129 reads (21%) | catalogued as rs749139073, COSV100510781; called by muse, mutect2, varscan2
- GPBP1 | c.660A>G p.T220= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV99302665; called by muse, mutect2, varscan2
- HORMAD1 | c.840G>A p.Q280= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as COSV100463999; called by muse, mutect2, varscan2
- HSD17B11 | c.120G>T p.L40= | Silent (SNP) | VAF 57/177 reads (32%) | catalogued as COSV100839564; called by muse, mutect2, varscan2
- KCNC2 | c.312C>T p.F104= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV54382020; called by muse, mutect2, varscan2
- KIF4B | c.3585G>A p.S1195= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV70529673; called by muse, mutect2, varscan2
- MUC5B | c.9300G>A p.P3100= | Silent (SNP) | VAF 60/206 reads (29%) | catalogued as rs754160190, COSV71590663; called by muse, mutect2, varscan2
- PCDHGC3 | c.1572C>T p.P524= | Silent (SNP) | VAF 41/142 reads (29%) | catalogued as COSV99339272; called by muse, mutect2, varscan2
- RANBP3L | c.54C>A p.T18= | Silent (SNP) | VAF 65/197 reads (33%) | catalogued as COSV99683720; called by muse, mutect2, varscan2
- RXRA | c.696G>A p.V232= | Silent (SNP) | VAF 44/127 reads (35%) | catalogued as COSV100709224; called by muse, mutect2, varscan2
- SCN2A | c.5967C>T p.D1989= | Silent (SNP) | VAF 35/96 reads (36%) | catalogued as rs1420332215, COSV99330975; called by muse, mutect2, varscan2
- SEPTIN14 | c.618G>A p.T206= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as rs775456195, COSV66429452; called by muse, mutect2, varscan2
- SLC35F3 | c.111G>A p.A37= (on ENST00000366617 / NM_001300845.1; = p.A106= on NM_173508.4) | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as rs752441220, COSV64018569; called by muse, varscan2
- SYTL1 | c.516G>A p.A172= (on ENST00000543823; = p.A160= on NM_032872.3) | Silent (SNP) | VAF 39/123 reads (32%) | catalogued as rs537719164, COSV100539253; called by muse, mutect2, varscan2
- TRPM2 | c.4395C>T p.H1465= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as rs374406565; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF41 | c.936C>A p.P312= | Silent (SNP) | VAF 112/306 reads (37%) | catalogued as COSV100491969; called by muse, mutect2, varscan2
- ZNF84 | c.135G>A p.V45= | Silent (SNP) | VAF 73/237 reads (31%) | called by muse, mutect2, varscan2
- SNORD116-27 | n.88G>C | RNA (SNP) | VAF 41/122 reads (34%) | called by muse, mutect2, varscan2
